HCMI case HCM-EXPT-1155-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/eda3273d-5f57-44d9-ac72-7b3eba91689c

Demographics
Sex at birth: male; Year of birth: 1952.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 67.6 years (24,681 days); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Neoadjuvant.

Biospecimens (1 sample)
- Sample HCM-EXPT-1155-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
